TCGA case TCGA-ER-A1A1 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1251acee-ceb4-4530-ba5b-4d163fcab8d2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Classification of tumor: Progression; Age at diagnosis: 58.2 years (21,256 days); Days to diagnosis: 47 days; Prior treatment: No; Days to last follow up: 3,196 days (8.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.1 years (21,209 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: TX; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 418 days (1.1 years); Route of administration: Intravenous / Subcutaneous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 161 days; Days to treatment end: 206 days; Number of fractions: 30; Treatment anatomic sites: Regional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 2 of this record; Age at diagnosis: 63.5 years (23,180 days); Days to diagnosis: 1,971 days (5.4 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 1,971 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,433 days (6.7 years); Disease response: Tumor Free.
- Days to follow up: 3,196 days (8.8 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ER-A1A1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-ER-A1A1-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ER-A1A1-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ER-A1A1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.
- Drug treatment: Regimen number: 96-99.
- Drug treatment, Route of administrations: Route of administration: IV; Route of administration: SC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,196 days; disease-specific survival: no event (censored), 3,196 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,971 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ER-A1A1-06A-11D-A191-01): tumor purity 0.2, ploidy 2, whole-genome doublings 0.
